Somatic mutation profile of tumor specimen TCGA-10-0934-01A (aliquot TCGA-10-0934-01A-02D-0399-01) from TCGA case TCGA-10-0934, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 50.9 years (18,602 days).
Specimen TCGA-10-0934-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9da0d27-468e-459e-b099-921930d4fa57.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-10-0934-11A (Solid Tissue Normal), aliquot TCGA-10-0934-11A-01D-0399-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d1723bc-b132-4f00-be2e-c777ef3f2588

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 12, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 19/47 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 44/98 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ARHGEF7 | c.67A>C p.T23P | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.653); catalogued as rs746874740, COSV100404454, COSV57730780; called by muse, mutect2, varscan2
- DCUN1D4 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 81/179 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as rs758671159, COSV58121065; called by muse, mutect2, varscan2
- DLGAP3 | c.2041G>A p.V681M | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1291733500, COSV52391941; called by muse, mutect2, varscan2
- DNMBP | c.3461G>A p.R1154Q | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs547189728, COSV60621466; called by muse, mutect2, varscan2
- GEN1 | c.1217G>T p.R406L | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1183092755, COSV100437752, COSV58056387; called by muse, mutect2, varscan2
- KCNH2 | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs764666519, COSV51132535; called by muse, mutect2, varscan2
- ROBO3 | c.3074C>T p.A1025V | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1189571607, COSV67299601; called by muse, varscan2
- SPAST | c.209A>C p.H70P | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.099); catalogued as COSV100188286; called by muse, varscan2
- SRD5A2 | c.305A>G p.N102S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs1418439291, COSV51870651; called by muse, mutect2, varscan2
- XKR6 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.534); catalogued as rs201821196; called by muse, mutect2, varscan2
- PKHD1L1 | c.4443C>T p.S1481= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as rs763983259, COSV65738582; called by muse, mutect2
- PRX | c.1647G>A p.P549= | Silent (SNP) | VAF 104/258 reads (40%) | catalogued as rs202113722, COSV52527803, COSV52528592; called by muse, varscan2
- ZNF714 | c.879T>A p.A293= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV52510088; called by muse, mutect2, varscan2
